Somatic mutation profile of tumor specimen C3N-00203-03 (aliquot CPT0090340009) from CPTAC case C3N-00203, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 72.2 years (26,353 days).
Specimen C3N-00203-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 126107ff-ba78-459b-a7d4-eb7685d71ca1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00203-31 (Blood Derived Normal), aliquot CPT0092480002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/987e9c0c-bc1e-4446-8b52-b261555e949f

The open-access MAF lists 569 somatic variants for this specimen: 400 protein-altering or splice-affecting, 110 silent, 59 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 336, Silent 110, Nonsense Mutation 30, Intron 27, Frame Shift Del 13, RNA 13, Splice Site 11, 5'UTR 9, 3'Flank 4, Frame Shift Ins 4, Splice Region 4, 5'Flank 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 26/107 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 125/337 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.12264G>A p.M4088I | Missense Mutation (SNP) | VAF 35/200 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746929143; called by muse, mutect2, varscan2
- ADAMTS3 | c.1507A>G p.K503E | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1338410993; called by muse, varscan2
- ADCY1 | c.2502G>T p.R834S | Missense Mutation (SNP) | VAF 64/284 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as COSV52034209; called by muse, mutect2, varscan2
- ADGRG3 | c.268C>G p.P90A | Missense Mutation (SNP) | VAF 44/261 reads (17%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs200028157, COSV59652778; called by muse, mutect2, varscan2
- ANK2 | c.1023G>T p.Q341H | Missense Mutation (SNP) | VAF 83/444 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.715); catalogued as COSV52191759; called by muse, mutect2, varscan2
- ANK2 | c.1024G>T p.G342* | Nonsense Mutation (SNP) | VAF 84/449 reads (19%) | catalogued as COSV52191346; called by muse, mutect2, varscan2
- APOB | c.1429G>A p.D477N | Missense Mutation (SNP) | VAF 120/627 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99264853; called by muse, mutect2, varscan2
- BLK | c.618T>C p.S206= | Splice Region (SNP) | VAF 23/150 reads (15%) | catalogued as rs1440557022; called by muse, mutect2, varscan2
- CA5A | c.439G>T p.G147C | Missense Mutation (SNP) | VAF 56/216 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV59240027; called by muse, mutect2, varscan2
- CARD10 | c.2117C>A p.P706H | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV99324845; called by muse, mutect2, varscan2
- CDH18 | c.1820C>T p.S607F | Missense Mutation (SNP) | VAF 37/229 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.037); catalogued as rs1313739373; called by muse, mutect2, varscan2
- CDIN1 | c.760G>C p.E254Q (on ENST00000437989; = p.E156Q on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/208 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as COSV100589839; called by muse, mutect2, varscan2
- CDK13 | c.973A>T p.S325C | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as rs911501491; called by muse, mutect2, varscan2
- CFAP46 | c.6125C>A p.A2042E | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99584421; called by muse, mutect2, varscan2
- CHRM2 | c.1087C>A p.R363S | Missense Mutation (SNP) | VAF 102/395 reads (26%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.448); catalogued as rs772049510, COSV99062900; called by muse, mutect2, varscan2
- CLHC1 | c.1525G>A p.G509S | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as COSV68464397; called by muse, mutect2, varscan2
- COL28A1 | c.3187C>T p.P1063S | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1277982252; called by muse, mutect2, varscan2
- CSMD2 | c.4336G>A p.G1446R | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1433283674; called by muse, mutect2, varscan2
- CSMD2 | c.584C>T p.S195F | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV53949979; called by muse, mutect2, varscan2
- CSMD3 | c.8043C>A p.S2681R (on ENST00000297405 / NM_001363185.1; = p.S2577R on NM_052900.3) | Missense Mutation (SNP) | VAF 111/331 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52342083; called by muse, mutect2, varscan2
- DAAM2 | c.370G>C p.E124Q | Missense Mutation (SNP) | VAF 42/319 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.2); catalogued as COSV51306061; called by muse, mutect2, varscan2
- DACH2 | c.361G>A p.V121M | Missense Mutation (SNP) | VAF 18/156 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64173724; called by muse, mutect2, varscan2
- DCAF4L2 | c.131G>T p.R44L | Missense Mutation (SNP) | VAF 49/461 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100150443; called by muse, mutect2, varscan2
- DDX60L | c.3100G>T p.E1034* | Nonsense Mutation (SNP) | VAF 41/185 reads (22%) | catalogued as COSV52717115; called by muse, mutect2, varscan2
- DENND1A | c.925G>T p.A309S | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.067); catalogued as rs750645781; called by muse, mutect2, varscan2
- DHX36 | c.2011A>G p.I671V | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.401); catalogued as rs763701497; called by muse, mutect2
- DNAH3 | c.10060A>G p.T3354A | Missense Mutation (SNP) | VAF 106/288 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1400664348; called by muse, mutect2, varscan2
- DRP2 | c.2491C>A p.R831S | Missense Mutation (SNP) | VAF 397/512 reads (78%) | SIFT tolerated (0.17); PolyPhen benign (0.048); catalogued as COSV67871057; called by muse, mutect2, varscan2
- DYNC1H1 | c.6406-4G>C | Splice Region (SNP) | VAF 26/235 reads (11%) | catalogued as rs374602014; ClinVar: likely benign; called by muse, mutect2, varscan2
- ECD | c.1895A>G p.N632S | Missense Mutation (SNP) | VAF 102/212 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.114); catalogued as rs1003723347; called by muse, varscan2
- EVX1 | c.187G>A p.G63R | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.205); catalogued as rs993150459; called by muse, mutect2, varscan2
- F9 | c.677G>T p.R226L | Missense Mutation (SNP) | VAF 193/327 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.55); catalogued as CM940541, CM940542, CM940543, COSV54380883; called by muse, mutect2, varscan2
- FAM135B | c.1804C>T p.Q602* | Nonsense Mutation (SNP) | VAF 110/234 reads (47%) | catalogued as COSV52708219; called by muse, mutect2, varscan2
- FLG | c.9902G>T p.R3301I | Missense Mutation (SNP) | VAF 123/516 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771935060; called by muse, mutect2, varscan2
- FLG2 | c.3212C>A p.S1071* | Nonsense Mutation (SNP) | VAF 115/604 reads (19%) | catalogued as COSV66173876; called by muse, mutect2, varscan2
- FO393400.1 | c.136G>C p.E46Q | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.982); catalogued as COSV99640669; called by muse, mutect2, varscan2
- GALNT9 | c.1694del p.G565Afs*29 (on ENST00000328957 / NM_001122636.2; = p.G199Afs*29 on NM_021808.3) | Frame Shift Del (DEL) | VAF 42/240 reads (18%) | catalogued as COSV100201305; called by mutect2, pindel, varscan2
- GBP6 | c.229G>C p.G77R | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770541907; called by muse, mutect2, varscan2
- GLI3 | c.415G>T p.A139S | Missense Mutation (SNP) | VAF 85/373 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.621); catalogued as COSV101230133, COSV67887651; called by muse, mutect2, varscan2
- GRIK3 | c.1639C>A p.P547T | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.682); catalogued as rs1175225920; called by muse, mutect2, varscan2
- GRIN2B | c.2780G>A p.R927Q | Missense Mutation (SNP) | VAF 83/429 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.97); catalogued as rs199677214; called by muse, mutect2, varscan2
- GRM7 | c.1598A>G p.K533R | Missense Mutation (SNP) | VAF 25/219 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.373); catalogued as rs1363938822; called by muse, mutect2, varscan2
- H2AC1 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV51237537; called by muse, mutect2, varscan2
- HELZ2 | c.6367G>C p.G2123R (on ENST00000467148 / NM_001037335.2; = p.G1554R on NM_033405.3) | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as rs750610107, COSV71296367; called by muse, mutect2, varscan2
- HSPG2 | c.5245C>T p.R1749C | Missense Mutation (SNP) | VAF 100/379 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs751244526, COSV101020644; called by muse, mutect2, varscan2
- IGKV1-6 | c.268G>A p.G90S | Missense Mutation (SNP) | VAF 143/607 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs758468017; called by muse, mutect2, varscan2
- ITGA6 | c.2941C>T p.R981W (on ENST00000442250; = p.R942W on NM_000210.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 220/625 reads (35%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.761); catalogued as rs765042466, COSV51233036; called by muse, mutect2, varscan2
- KCNH1 | c.1831G>A p.A611T (on ENST00000271751 / NM_172362.3; = p.A584T on NM_002238.4) | Missense Mutation (SNP) | VAF 27/186 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.038); catalogued as rs1383990598; called by muse, mutect2, varscan2
- KCNV2 | c.728G>A p.R243Q | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.16); catalogued as COSV66057534; called by muse, mutect2, varscan2
- KDR | c.3425G>T p.C1142F | Missense Mutation (SNP) | VAF 92/391 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55759623; called by muse, mutect2, varscan2
- KIAA0895 | c.1357C>T p.R453* (on ENST00000297063 / NM_001100425.2; = p.R402* on NM_015314.3) | Nonsense Mutation (SNP) | VAF 32/167 reads (19%) | catalogued as rs751552500; called by muse, mutect2, varscan2
- LAMA2 | c.1756G>A p.A586T | Missense Mutation (SNP) | VAF 52/207 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs752648056; called by muse, mutect2, varscan2
- LRP1 | c.9844C>T p.H3282Y | Missense Mutation (SNP) | VAF 35/175 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.142); catalogued as COSV54510122; called by muse, mutect2, varscan2
- LRRC10 | c.274C>A p.Q92K | Missense Mutation (SNP) | VAF 42/275 reads (15%) | SIFT tolerated (0.88); PolyPhen benign (0.014); catalogued as rs1164726774; called by muse, mutect2, varscan2
- LYPD4 | c.467A>G p.N156S | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs1335454132; called by muse, mutect2, varscan2
- MATN1 | c.580G>C p.E194Q | Missense Mutation (SNP) | VAF 36/149 reads (24%) | SIFT tolerated (0.17); PolyPhen benign (0.12); catalogued as COSV101056187; called by muse, mutect2, varscan2
- MDM4 | c.755G>T p.G252V | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.212); catalogued as COSV100914413; called by muse, mutect2, varscan2
- MGAT4C | c.596G>T p.R199L | Missense Mutation (SNP) | VAF 29/202 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770702724, COSV59832815, COSV59833353; called by muse, mutect2, varscan2
- MLIP | c.196A>G p.K66E | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0.034); catalogued as rs770944621; called by muse, mutect2, varscan2
- MNX1 | c.878G>C p.R293P | Missense Mutation (SNP) | VAF 88/584 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM003828, COSV53319628; called by muse, mutect2, varscan2
- MUC16 | c.40210C>A p.P13404T | Missense Mutation (SNP) | VAF 29/189 reads (15%) | SIFT tolerated, low confidence (0.32); PolyPhen probably damaging (0.99); catalogued as COSV101110087; called by muse, mutect2, varscan2
- MYH2 | c.3478G>T p.G1160C | Missense Mutation (SNP) | VAF 148/499 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55434554; called by muse, mutect2, varscan2
- MYH7 | c.1203C>G p.H401Q | Missense Mutation (SNP) | VAF 42/534 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV62525585; called by muse, mutect2
- MYH8 | c.3587G>A p.R1196Q | Missense Mutation (SNP) | VAF 76/334 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1340594495, COSV101238166, COSV67972640; called by muse, varscan2
- MYO5B | c.2044G>T p.G682W | Missense Mutation (SNP) | VAF 72/302 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53217734, COSV99543874; called by muse, mutect2, varscan2
- MYOM3 | c.3230C>A p.S1077* | Nonsense Mutation (SNP) | VAF 50/254 reads (20%) | catalogued as COSV58395358; called by muse, mutect2, varscan2
- NCOR1 | c.1241G>T p.R414L | Missense Mutation (SNP) | VAF 33/163 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52000356; called by muse, mutect2, varscan2
- NEB | c.7906G>T p.D2636Y | Missense Mutation (SNP) | VAF 38/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51424010, COSV51437656; called by muse, mutect2
- NECTIN3 | c.151A>G p.R51G | Missense Mutation (SNP) | VAF 19/100 reads (19%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1238213906; called by muse, mutect2, varscan2
- NELL2 | c.324C>G p.H108Q | Missense Mutation (SNP) | VAF 51/234 reads (22%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.761); catalogued as COSV100419653; called by muse, mutect2, varscan2
- NIPBL | c.251G>C p.G84A | Missense Mutation (SNP) | VAF 63/399 reads (16%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.995); catalogued as COSV99238473; called by muse, mutect2, varscan2
- NLRP3 | c.1115C>A p.S372Y | Missense Mutation (SNP) | VAF 38/342 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100276559, COSV60220608; called by muse, mutect2, varscan2
- NPAP1 | c.1397C>A p.P466H | Missense Mutation (SNP) | VAF 47/271 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.32); catalogued as COSV61504435; called by muse, mutect2, varscan2
- NPHP3 | c.1838G>T p.R613L | Missense Mutation (SNP) | VAF 32/402 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV58629889; called by muse, mutect2
- NYAP1 | c.1888G>T p.G630C | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.648); catalogued as rs780012281; called by muse, mutect2, varscan2
- OR10X1 | c.433C>A p.P145T | Missense Mutation (SNP) | VAF 76/383 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as rs778948887; called by muse, mutect2, varscan2
- OR10Z1 | c.601A>T p.I201F | Missense Mutation (SNP) | VAF 73/321 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.024); catalogued as rs749568343; called by muse, mutect2, varscan2
- OR2W1 | c.312C>G p.Y104* | Nonsense Mutation (SNP) | VAF 46/226 reads (20%) | catalogued as COSV65851914; called by muse, mutect2, varscan2
- OR4M1 | c.760G>C p.G254R | Missense Mutation (SNP) | VAF 35/543 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as COSV60062819; called by muse, mutect2
- OR4N2 | c.721A>G p.I241V | Missense Mutation (SNP) | VAF 79/1152 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs766284352; called by muse, mutect2
- OR6Y1 | c.383A>T p.Y128F | Missense Mutation (SNP) | VAF 91/417 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.248); catalogued as rs751744042, COSV56930478; called by muse, mutect2, varscan2
- PAXIP1 | c.524A>G p.K175R | Missense Mutation (SNP) | VAF 68/260 reads (26%) | SIFT tolerated (0.85); PolyPhen benign (0.023); catalogued as rs1227774485; called by muse, mutect2, varscan2
- PCDHA1 | c.871G>C p.E291Q | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.072); catalogued as COSV65375675; called by muse, mutect2, varscan2
- PDE1A | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1299899331, COSV100113545; called by muse, mutect2, varscan2
- PHYHIP | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as rs1290538818; called by muse, mutect2, varscan2
- PKHD1L1 | c.7102G>T p.G2368* | Nonsense Mutation (SNP) | VAF 29/293 reads (10%) | catalogued as COSV101006042; called by muse, mutect2, varscan2
- PPDPFL | c.118G>A p.D40N | Missense Mutation (SNP) | VAF 26/190 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.013); catalogued as rs1212695465, COSV57462436; called by muse, mutect2, varscan2
- PRAMEF12 | c.1399C>A p.L467M | Missense Mutation (SNP) | VAF 64/273 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.97); catalogued as COSV63216007; called by muse, mutect2, varscan2
- PRDM10 | c.2818C>G p.Q940E | Missense Mutation (SNP) | VAF 72/274 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.547); catalogued as COSV58800037; called by muse, mutect2, varscan2
- PREX2 | c.2974A>T p.I992F | Missense Mutation (SNP) | VAF 26/220 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.957); catalogued as COSV55801783; called by muse, mutect2, varscan2
- PRKG1 | c.1430G>T p.R477I | Missense Mutation (SNP) | VAF 158/340 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV64778093; called by muse, mutect2, varscan2
- PRLH | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.662); catalogued as rs927642196; called by muse, mutect2, varscan2
- PRSS55 | c.1019G>A p.C340Y | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV100153902; called by muse, mutect2
- PTH2R | c.944A>G p.K315R | Missense Mutation (SNP) | VAF 38/256 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.25); catalogued as rs768530624; called by muse, mutect2, varscan2
- PTPN7 | c.989+1G>A p.X330_splice (on ENST00000495688; = p.X369_splice on NM_002832.4 and 3 other RefSeq transcripts) | Splice Site (SNP) | VAF 82/173 reads (47%) | catalogued as COSV58313044; called by muse, mutect2, varscan2
- REG3A | c.242G>T p.S81I | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100532639; called by muse, mutect2, varscan2
- REN | c.689G>T p.R230I | Missense Mutation (SNP) | VAF 46/478 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as CM053392; called by muse, mutect2
- RGS7 | c.742C>A p.P248T | Missense Mutation (SNP) | VAF 83/334 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.388); catalogued as COSV100469577; called by muse, mutect2, varscan2
- RIMS1 | c.2539G>T p.G847* | Nonsense Mutation (SNP) | VAF 31/123 reads (25%) | catalogued as rs867659809; called by muse, mutect2, varscan2
- RIN2 | c.2698A>G p.T900A (on ENST00000255006 / NM_001242581.1; = p.T851A on NM_018993.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 78/312 reads (25%) | SIFT tolerated (0.77); PolyPhen probably damaging (0.995); catalogued as rs1222661351; called by muse, mutect2, varscan2
- RNGTT | c.653T>A p.F218Y | Missense Mutation (SNP) | VAF 45/169 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1360382351; called by muse, mutect2, varscan2
- RTL1 | c.3883C>T p.R1295C | Missense Mutation (SNP) | VAF 38/317 reads (12%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.446); catalogued as rs1488343713; called by muse, mutect2, varscan2
- RYR1 | c.6407G>T p.R2136L | Missense Mutation (SNP) | VAF 140/534 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV62103633; called by muse, mutect2, varscan2
- RYR2 | c.3658G>C p.D1220H | Missense Mutation (SNP) | VAF 74/359 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as rs753078642; called by muse, mutect2, varscan2
- RYR2 | c.5239G>C p.G1747R | Missense Mutation (SNP) | VAF 57/298 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV100771968, COSV63696153; called by muse, mutect2, varscan2
- SCARF1 | c.2000G>A p.G667D | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.213); catalogued as COSV53957570; called by muse, mutect2, varscan2
- SFMBT2 | c.2243C>T p.S748L | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.185); catalogued as rs767676222; called by muse, mutect2, varscan2
- SIGLEC1 | c.4733C>T p.P1578L | Missense Mutation (SNP) | VAF 56/277 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as rs889151021; called by muse, mutect2, varscan2
- SLC27A2 | c.1223G>T p.R408L | Missense Mutation (SNP) | VAF 28/171 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs755863102; called by muse, mutect2, varscan2
- SLC28A1 | c.693C>A p.F231L | Missense Mutation (SNP) | VAF 108/479 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99723531; called by muse, mutect2, varscan2
- SOX12 | c.352del p.A118Rfs*181 | Frame Shift Del (DEL) | VAF 24/80 reads (30%) | catalogued as COSV61259200; called by mutect2, pindel, varscan2
- SPHKAP | c.1627G>T p.G543* | Nonsense Mutation (SNP) | VAF 18/268 reads (7%) | catalogued as COSV100763912; called by muse, mutect2
- SPRED1 | c.80C>A p.S27* | Nonsense Mutation (SNP) | VAF 104/411 reads (25%) | catalogued as COSV100136405, COSV54437594; called by muse, mutect2, varscan2
- SYNJ1 | c.2141G>T p.R714L | Missense Mutation (SNP) | VAF 8/206 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100449460; called by muse, mutect2
- TFPI2 | c.158A>G p.Y53C | Missense Mutation (SNP) | VAF 35/173 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1421280720; called by muse, mutect2, varscan2
- TMEM132D | c.968+1G>T p.X323_splice | Splice Site (SNP) | VAF 20/88 reads (23%) | catalogued as COSV101395845; called by muse, varscan2
- TRIM61 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 89/729 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.229); catalogued as COSV61418698; called by muse, mutect2, varscan2
- TRPM3 | c.1283C>T p.T428M (on ENST00000357533 / NM_001366142.2; = p.T273M on NM_020952.6) | Missense Mutation (SNP) | VAF 50/206 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs766391304, COSV100676574; called by muse, mutect2, varscan2
- TSPAN11 | c.498del p.H166Qfs*141 | Frame Shift Del (DEL) | VAF 44/157 reads (28%) | catalogued as COSV53819409; called by mutect2, pindel, varscan2
- TTN | c.26827G>T p.A8943S (on ENST00000591111; = p.A8016S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 101/274 reads (37%) | PolyPhen probably damaging (0.996); catalogued as rs777920428; called by muse, mutect2, varscan2
- TTN | c.25424C>A p.A8475E (on ENST00000591111; = p.A7548E on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 53/355 reads (15%) | PolyPhen possibly damaging (0.551); catalogued as rs761198294, COSV60318170; called by muse, mutect2, varscan2
- TTN | c.14788G>T p.G4930* (on ENST00000591111; = p.G4003* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 26/134 reads (19%) | catalogued as COSV60292507; called by muse, varscan2
- TUBB4A | c.914C>G p.P305R | Missense Mutation (SNP) | VAF 82/427 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1338934761; called by muse, mutect2, varscan2
- UNC13C | c.517C>A p.L173I | Missense Mutation (SNP) | VAF 31/169 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.991); catalogued as COSV99522720; called by muse, mutect2, varscan2
- UNC80 | c.3679C>G p.R1227G | Missense Mutation (SNP) | VAF 78/393 reads (20%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.992); catalogued as rs1381846226; called by muse, mutect2, varscan2
- USP25 | c.1086G>T p.W362C | Missense Mutation (SNP) | VAF 18/116 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1252686980; called by muse, varscan2
- UTP20 | c.1474G>T p.E492* | Nonsense Mutation (SNP) | VAF 14/64 reads (22%) | catalogued as COSV55371548; called by muse, mutect2, varscan2
- XIRP2 | c.3905T>A p.V1302D (on ENST00000628543; = p.V1477D on NM_152381.6) | Missense Mutation (SNP) | VAF 48/257 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773692211; called by muse, mutect2, varscan2
- ZBTB5 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 44/222 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV57038720; called by muse, mutect2, varscan2
- ZCCHC13 | c.253C>G p.R85G | Missense Mutation (SNP) | VAF 70/188 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as COSV59866406; called by muse, mutect2, varscan2
- ZMAT1 | c.769G>T p.E257* | Nonsense Mutation (SNP) | VAF 62/447 reads (14%) | catalogued as COSV65658038; called by muse, mutect2, varscan2
- ZNF208 | c.1123G>A p.G375S | Missense Mutation (SNP) | VAF 39/316 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs762120661; called by muse, mutect2, varscan2
- ZNF786 | c.535G>A p.V179I | Missense Mutation (SNP) | VAF 244/572 reads (43%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1374011634; called by muse, mutect2, varscan2
- ABCA2 | c.3037G>T p.E1013* (on ENST00000614293; = p.E983* on NM_001606.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 22/213 reads (10%) | called by muse, mutect2
- AC011005.1 | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 266/775 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADAM18 | c.1392C>G p.C464W | Missense Mutation (SNP) | VAF 59/406 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAMTS16 | c.1595A>T p.D532V | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); called by muse, mutect2, varscan2
- ADAMTS2 | c.1936C>T p.H646Y | Missense Mutation (SNP) | VAF 45/265 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAMTS8 | c.1478T>A p.L493Q | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ADAMTSL4 | c.1729_1731dup p.T577dup | In Frame Ins (INS) | VAF 19/151 reads (13%) | called by mutect2, varscan2
- ADCY2 | c.913G>T p.D305Y | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- ADGB | c.1996T>A p.S666T | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, varscan2
- ADGB | c.3595C>A p.Q1199K | Missense Mutation (SNP) | VAF 31/121 reads (26%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADGRE1 | c.1476G>T p.E492D | Missense Mutation (SNP) | VAF 53/285 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- AGBL1 | c.1744G>T p.E582* | Nonsense Mutation (SNP) | VAF 17/76 reads (22%) | called by muse, mutect2, varscan2
- AKAP6 | c.6447G>T p.K2149N | Missense Mutation (SNP) | VAF 81/308 reads (26%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- AKNAD1 | c.728C>T p.S243L | Missense Mutation (SNP) | VAF 50/232 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- ANK1 | c.2840C>A p.T947N | Missense Mutation (SNP) | VAF 37/369 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANKRD34C | c.1005A>C p.K335N | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- ANKRD62 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKS6 | c.1329G>T p.W443C | Missense Mutation (SNP) | VAF 75/307 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- AP1G2 | c.839A>C p.D280A | Missense Mutation (SNP) | VAF 39/161 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- APEH | c.261G>T p.E87D | Missense Mutation (SNP) | VAF 60/263 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ARFGEF2 | c.2983T>C p.C995R | Missense Mutation (SNP) | VAF 70/524 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ARID3C | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 31/185 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- ARL5C | c.304A>T p.T102S | Missense Mutation (SNP) | VAF 134/324 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ASH1L | c.3919A>T p.S1307C | Missense Mutation (SNP) | VAF 72/248 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- ASTN2 | c.355C>G p.L119V | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, varscan2
- ATP12A | c.367G>T p.A123S | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- ATRAID | c.268T>A p.C90S (on ENST00000611786; = p.C35S on NM_001170795.3) | Missense Mutation (SNP) | VAF 53/182 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- AXDND1 | c.1646A>G p.Q549R | Missense Mutation (SNP) | VAF 28/273 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.755); called by muse, mutect2, varscan2
- BMP6 | c.1115C>A p.T372N | Missense Mutation (SNP) | VAF 258/686 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- C3orf20 | c.2111C>A p.P704H | Missense Mutation (SNP) | VAF 91/487 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C9orf78 | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 26/284 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CACNA1I | c.3572G>T p.R1191L | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CADPS | c.1326-1G>C p.X442_splice | Splice Site (SNP) | VAF 34/121 reads (28%) | called by muse, mutect2, varscan2
- CALCRL | c.842+1G>A p.X281_splice | Splice Site (SNP) | VAF 18/174 reads (10%) | called by muse, mutect2
- CAMK2A | c.585C>A p.D195E | Missense Mutation (SNP) | VAF 50/157 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- CAMK2B | c.1322G>T p.S441I | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.015); called by muse, mutect2
- CAPSL | c.458G>T p.W153L | Missense Mutation (SNP) | VAF 37/220 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CASP4 | c.604A>T p.S202C | Missense Mutation (SNP) | VAF 182/490 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- CATSPERD | c.1726G>T p.V576F | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CCDC63 | c.77A>T p.Q26L | Missense Mutation (SNP) | VAF 69/284 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC93 | c.271G>T p.V91F | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCIN | c.466A>T p.I156F | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CDH17 | c.1705C>A p.H569N | Missense Mutation (SNP) | VAF 48/523 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.001); called by muse, mutect2
- CDK5RAP2 | c.507+1G>T p.X169_splice | Splice Site (SNP) | VAF 98/374 reads (26%) | called by muse, mutect2, varscan2
- CEP83 | c.1506G>T p.M502I | Missense Mutation (SNP) | VAF 46/299 reads (15%) | SIFT tolerated (0.37); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- CES5A | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 48/242 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CGB5 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 41/218 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- CHMP3 | c.67A>T p.I23L | Missense Mutation (SNP) | VAF 51/231 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CILP2 | c.2332T>A p.W778R | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTNAP3 | c.2312G>C p.R771P | Missense Mutation (SNP) | VAF 58/221 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- COLEC12 | c.1444G>T p.G482C | Missense Mutation (SNP) | VAF 55/204 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CPED1 | c.2263G>C p.G755R | Missense Mutation (SNP) | VAF 153/465 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- CRB1 | c.2511C>A p.D837E | Missense Mutation (SNP) | VAF 114/438 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- CRISP2 | c.321G>C p.W107C | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CTTNBP2 | c.4059G>T p.W1353C | Missense Mutation (SNP) | VAF 190/429 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CWH43 | c.1050T>A p.D350E | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.163); called by muse, varscan2
- CXCR1 | c.509C>A p.P170H | Missense Mutation (SNP) | VAF 141/555 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DAPK1 | c.1166G>T p.C389F | Missense Mutation (SNP) | VAF 56/256 reads (22%) | SIFT tolerated (0.65); PolyPhen possibly damaging (0.876); called by muse, varscan2
- DBX2 | c.836T>C p.I279T | Missense Mutation (SNP) | VAF 40/162 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- DLGAP1 | c.1414G>T p.E472* | Nonsense Mutation (SNP) | VAF 58/248 reads (23%) | called by muse, mutect2, varscan2
- DLL3 | c.1279del p.R427Afs*121 | Frame Shift Del (DEL) | VAF 30/105 reads (29%) | called by mutect2, pindel, varscan2
- DMKN | c.159G>T p.K53N | Missense Mutation (SNP) | VAF 327/694 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- DMRT3 | c.563G>C p.G188A | Missense Mutation (SNP) | VAF 51/214 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- DNAH6 | c.266A>T p.Y89F | Missense Mutation (SNP) | VAF 129/388 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DNAH6 | c.8992A>T p.I2998L | Missense Mutation (SNP) | VAF 36/194 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- DPP4 | c.1420G>T p.G474C | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DUSP22 | c.379C>T p.P127S | Missense Mutation (SNP) | VAF 38/494 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DUSP22 | c.380C>T p.P127L | Missense Mutation (SNP) | VAF 39/488 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DYNC1LI2 | c.1204A>T p.S402C | Missense Mutation (SNP) | VAF 45/171 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- EGFR | c.1436A>T p.K479I | Missense Mutation (SNP) | VAF 56/274 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ELFN2 | c.904C>A p.H302N | Missense Mutation (SNP) | VAF 36/120 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EPB41L3 | c.937T>A p.L313I | Missense Mutation (SNP) | VAF 54/212 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- ERICH3 | c.883G>T p.G295W | Missense Mutation (SNP) | VAF 32/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FAAH | c.1004A>C p.Y335S | Missense Mutation (SNP) | VAF 114/494 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- FAM171B | c.2324C>A p.P775H | Missense Mutation (SNP) | VAF 57/371 reads (15%) | SIFT tolerated (0.59); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- FANCB | c.935G>T p.W312L | Missense Mutation (SNP) | VAF 95/179 reads (53%) | SIFT tolerated (0.17); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- FAT1 | c.4139T>A p.I1380K | Missense Mutation (SNP) | VAF 70/309 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- FCGR2B | c.568C>A p.H190N | Missense Mutation (SNP) | VAF 68/372 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FCRL6 | c.469C>G p.Q157E | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); called by muse, mutect2, varscan2
- FGF3 | c.691G>T p.G231C | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- FGF3 | c.274T>A p.F92I | Missense Mutation (SNP) | VAF 130/528 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FKBP6 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 69/540 reads (13%) | called by muse, mutect2, varscan2
- FLG | c.7433A>G p.Y2478C | Missense Mutation (SNP) | VAF 156/548 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FLRT2 | c.577G>T p.A193S | Missense Mutation (SNP) | VAF 17/222 reads (8%) | SIFT tolerated (1); PolyPhen probably damaging (0.995); called by muse, mutect2
- FOXG1 | c.1210C>G p.P404A | Missense Mutation (SNP) | VAF 61/320 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.607); called by muse, mutect2, varscan2
- FOXP1 | c.1502A>G p.Y501C | Missense Mutation (SNP) | VAF 66/426 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GABRA1 | c.149T>A p.L50Q | Missense Mutation (SNP) | VAF 48/229 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRB3 | c.198C>A p.N66K | Missense Mutation (SNP) | VAF 45/338 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- GAD2 | c.76+1G>A p.X26_splice | Splice Site (SNP) | VAF 33/122 reads (27%) | called by muse, mutect2, varscan2
- GLI1 | c.974A>G p.H325R | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GOLGA5 | c.1301A>G p.K434R | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GPD1L | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.579); called by muse, mutect2
- GPR37 | c.347C>G p.P116R | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GPRASP1 | c.197T>A p.V66D | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- GREB1 | c.4943G>A p.C1648Y | Missense Mutation (SNP) | VAF 63/290 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- GRID2 | c.2160C>G p.N720K | Missense Mutation (SNP) | VAF 46/152 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- GRIK3 | c.1640C>A p.P547H | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- GRPR | c.31_32insC p.L11Sfs*23 | Frame Shift Ins (INS) | VAF 50/132 reads (38%) | called by mutect2, pindel, varscan2
- HCN1 | c.2389G>A p.V797M | Missense Mutation (SNP) | VAF 36/239 reads (15%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- HELZ2 | c.6368G>T p.G2123V (on ENST00000467148 / NM_001037335.2; = p.G1554V on NM_033405.3) | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- HIVEP3 | c.5885C>T p.P1962L | Missense Mutation (SNP) | VAF 25/191 reads (13%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HMCES | c.358G>T p.V120F | Missense Mutation (SNP) | VAF 103/282 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- HMGCR | c.952A>G p.M318V | Missense Mutation (SNP) | VAF 46/156 reads (29%) | SIFT tolerated (0.71); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- HOXA2 | c.200A>G p.H67R | Missense Mutation (SNP) | VAF 61/269 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IDH3B | c.170A>G p.D57G | Missense Mutation (SNP) | VAF 119/572 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IGHA1 | c.931T>A p.F311I | Missense Mutation (SNP) | VAF 119/985 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- IGKV1-17 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 109/580 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- IL18RAP | c.1595G>A p.R532K | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- IL26 | c.429G>T p.R143S | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- IPO9 | c.2854G>C p.E952Q | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.063); called by muse, varscan2
- ISLR2 | c.1132C>A p.P378T | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- ITIH6 | c.402del p.S135Afs*8 | Frame Shift Del (DEL) | VAF 77/182 reads (42%) | called by mutect2, pindel, varscan2
- JUP | c.119A>G p.K40R | Missense Mutation (SNP) | VAF 251/628 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNH7 | c.1448G>T p.S483I | Missense Mutation (SNP) | VAF 59/295 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- KCNN3 | c.1673C>A p.A558D (on ENST00000618040 / NM_001204087.1; = p.A543D on NM_002249.6) | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- KDM5D | c.1936G>T p.E646* | Nonsense Mutation (SNP) | VAF 109/234 reads (47%) | called by muse, mutect2, varscan2
- KIAA1217 | c.4261G>T p.E1421* | Nonsense Mutation (SNP) | VAF 60/270 reads (22%) | called by muse, mutect2, varscan2
- KIF14 | c.723G>C p.Q241H | Missense Mutation (SNP) | VAF 93/235 reads (40%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- KIR2DL3 | c.757G>A p.V253I | Missense Mutation (SNP) | VAF 98/351 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- LAMA1 | c.7981A>T p.S2661C | Missense Mutation (SNP) | VAF 86/395 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- LAMA1 | c.3933G>A p.M1311I | Missense Mutation (SNP) | VAF 83/472 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMB2 | c.3939G>T p.Q1313H | Missense Mutation (SNP) | VAF 139/580 reads (24%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.687); called by muse, mutect2, varscan2
- LARGE2 | c.1852C>A p.P618T | Missense Mutation (SNP) | VAF 94/322 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LCT | c.3451C>A p.L1151M | Missense Mutation (SNP) | VAF 32/143 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- LRRN3 | c.920A>G p.N307S | Missense Mutation (SNP) | VAF 47/326 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MAGEA6 | c.296C>A p.P99H | Missense Mutation (SNP) | VAF 187/330 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAGEB6 | c.724C>A p.Q242K | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- MAGEC1 | c.1535C>A p.S512Y | Missense Mutation (SNP) | VAF 67/235 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAPK8IP2 | c.1350G>T p.W450C | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- MAPKAPK5 | c.1231G>T p.E411* (on ENST00000551404 / NM_139078.3; = p.E409* on NM_003668.4 and 3 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 54/190 reads (28%) | called by muse, mutect2, varscan2
- MBNL2 | c.1096A>G p.I366V (on ENST00000376673 / NM_001382666.1; = p.I354V on NM_207304.3 and 13 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/279 reads (22%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0); called by muse, mutect2, varscan2
- MC1R | c.54del p.T19Qfs*33 | Frame Shift Del (DEL) | VAF 26/113 reads (23%) | called by mutect2, pindel, varscan2
- MEFV | c.518del p.G173Afs*22 | Frame Shift Del (DEL) | VAF 24/62 reads (39%) | called by mutect2, pindel, varscan2
- MFSD8 | c.256G>T p.G86C | Missense Mutation (SNP) | VAF 99/427 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MMP24 | c.487T>C p.W163R | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MOCS3 | c.904G>T p.E302* | Nonsense Mutation (SNP) | VAF 25/184 reads (14%) | called by muse, mutect2, varscan2
- MPP7 | c.1250A>T p.Y417F | Missense Mutation (SNP) | VAF 57/300 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRPS9 | c.497_498del p.Y166Wfs*36 | Frame Shift Del (DEL) | VAF 24/144 reads (17%) | called by pindel, varscan2
- MSANTD4 | c.403G>T p.G135C | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- MSH4 | c.1288C>A p.L430I | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- MSH6 | c.2536G>T p.E846* | Nonsense Mutation (SNP) | VAF 34/149 reads (23%) | called by muse, mutect2, varscan2
- MUC16 | c.40211C>A p.P13404H | Missense Mutation (SNP) | VAF 29/188 reads (15%) | SIFT tolerated, low confidence (0.4); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC22 | c.1780G>C p.E594Q | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT tolerated (0.33); called by muse, mutect2, varscan2
- MUC5B | c.16134T>A p.S5378= | Splice Region (SNP) | VAF 44/182 reads (24%) | called by muse, mutect2, varscan2
- MYH2 | c.-18C>A | Splice Region (SNP) | VAF 69/249 reads (28%) | called by muse, mutect2, varscan2
- MYH7 | c.27dup p.G10Wfs*23 | Frame Shift Ins (INS) | VAF 42/377 reads (11%) | called by mutect2, pindel, varscan2
- MYO6 | c.2932G>A p.E978K | Missense Mutation (SNP) | VAF 65/311 reads (21%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- MYOF | c.1436C>G p.T479S | Missense Mutation (SNP) | VAF 93/227 reads (41%) | SIFT tolerated (0.86); PolyPhen benign (0); called by muse, mutect2, varscan2
- NAAA | c.700G>T p.V234F | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- NAV3 | c.4984C>A p.L1662I | Missense Mutation (SNP) | VAF 40/166 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NBEAL1 | c.2558G>C p.R853T | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NEK1 | c.235G>T p.V79L | Missense Mutation (SNP) | VAF 42/215 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NLRP7 | c.848T>C p.L283P | Missense Mutation (SNP) | VAF 76/300 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NR1H4 | c.575G>T p.C192F (on ENST00000551379 / NM_001206993.2; = p.C182F on NM_005123.4) | Missense Mutation (SNP) | VAF 56/315 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NRXN3 | c.616C>A p.P206T | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- OR10J3 | c.128A>T p.N43I | Missense Mutation (SNP) | VAF 126/419 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- OR11H7 | c.728C>A p.S243* | Nonsense Mutation (SNP) | VAF 72/164 reads (44%) | called by muse, mutect2
- OR14A2 | c.720C>A p.F240L | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OR2T34 | c.592T>C p.S198P | Missense Mutation (SNP) | VAF 38/404 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.208); called by muse, mutect2
- OR4K2 | c.778T>A p.W260R | Missense Mutation (SNP) | VAF 75/748 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.68); called by muse, mutect2
- OR4M1 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 38/546 reads (7%) | SIFT tolerated (1); PolyPhen possibly damaging (0.896); called by muse, mutect2
- OR5B12 | c.749del p.Y250Lfs*29 | Frame Shift Del (DEL) | VAF 42/166 reads (25%) | called by mutect2, pindel, varscan2
- OR5B2 | c.848T>A p.L283Q | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- OR8B3 | c.302T>A p.L101Q | Missense Mutation (SNP) | VAF 58/328 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- OR8G5 | c.526del p.H176Ifs*10 | Frame Shift Del (DEL) | VAF 44/231 reads (19%) | called by mutect2, pindel, varscan2
- OR8S1 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 62/311 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OSMR | c.1095G>C p.L365F | Missense Mutation (SNP) | VAF 58/294 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0.184); called by muse, mutect2, varscan2
- OTOF | c.403G>T p.G135* | Nonsense Mutation (SNP) | VAF 92/395 reads (23%) | called by muse, mutect2, varscan2
- PAX7 | c.1273C>A p.Q425K | Missense Mutation (SNP) | VAF 42/445 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.212); called by muse, mutect2
- PCARE | c.1036T>G p.C346G | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- PCOLCE | c.319C>T p.R107W | Missense Mutation (SNP) | VAF 140/756 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- PDCD2L | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 11/317 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- PDS5B | c.4335A>T p.E1445D | Missense Mutation (SNP) | VAF 59/228 reads (26%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- PGA5 | c.1064C>A p.T355N | Missense Mutation (SNP) | VAF 134/578 reads (23%) | SIFT tolerated (0.5); PolyPhen benign (0.024); called by mutect2, varscan2
- PGAM4 | c.88C>A p.L30M | Missense Mutation (SNP) | VAF 85/164 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PIKFYVE | c.305G>T p.R102L | Missense Mutation (SNP) | VAF 112/516 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- PLEKHG7 | c.161T>A p.L54* | Nonsense Mutation (SNP) | VAF 68/280 reads (24%) | called by muse, mutect2, varscan2
- PMFBP1 | c.1942G>T p.E648* (on ENST00000537465; = p.E643* on NM_031293.3) | Nonsense Mutation (SNP) | VAF 31/183 reads (17%) | called by muse, mutect2, varscan2
- PODXL2 | c.448A>T p.N150Y | Missense Mutation (SNP) | VAF 97/266 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- POTEI | c.218G>T p.R73M | Missense Mutation (SNP) | VAF 180/852 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- POU5F2 | c.83G>T p.R28L | Missense Mutation (SNP) | VAF 38/110 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PRDM8 | c.1865C>A p.P622H | Missense Mutation (SNP) | VAF 87/404 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PRKCG | c.821+1G>T p.X274_splice | Splice Site (SNP) | VAF 17/61 reads (28%) | called by muse, mutect2, varscan2
- PRR23C | c.139G>A p.D47N | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.887); called by muse, mutect2
- PSMA2 | c.17A>G p.Y6C | Missense Mutation (SNP) | VAF 72/381 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PTK7 | c.2155G>T p.V719L | Missense Mutation (SNP) | VAF 88/462 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- PTPRK | c.2632C>G p.L878V (on ENST00000368215 / NM_001291984.2; = p.L879V on NM_002844.4) | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.664); called by muse, mutect2, varscan2
- RBBP5 | c.968A>G p.Q323R | Missense Mutation (SNP) | VAF 16/130 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- RBM45 | c.125G>T p.R42M | Missense Mutation (SNP) | VAF 92/500 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- REG3G | c.308G>T p.W103L | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RELCH | c.1183T>C p.F395L | Missense Mutation (SNP) | VAF 8/192 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.047); called by muse, mutect2
- RESF1 | c.2869G>C p.D957H | Missense Mutation (SNP) | VAF 71/290 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- RGSL1 | c.1195C>A p.L399I | Missense Mutation (SNP) | VAF 40/335 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RIMS1 | c.5006T>A p.L1669H | Missense Mutation (SNP) | VAF 54/155 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- RIMS2 | c.1330G>A p.D444N (on ENST00000666250 / NM_001348490.2; = p.D252N on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 28/353 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2
- RNASEH2A | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 138/625 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RTL9 | c.2091G>T p.M697I | Missense Mutation (SNP) | VAF 78/272 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RYR3 | c.3916C>A p.L1306M | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- RYR3 | c.5654A>C p.N1885T | Missense Mutation (SNP) | VAF 62/308 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SACS | c.9463C>G p.L3155V | Missense Mutation (SNP) | VAF 49/175 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- SCN8A | c.5548G>C p.A1850P | Missense Mutation (SNP) | VAF 106/486 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCP2 | c.1426del p.V476Wfs*3 | Frame Shift Del (DEL) | VAF 38/300 reads (13%) | called by mutect2, pindel, varscan2
- SENP7 | c.479A>T p.E160V | Missense Mutation (SNP) | VAF 44/225 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); called by muse, mutect2
- SHQ1 | c.883-2A>T p.X295_splice | Splice Site (SNP) | VAF 17/145 reads (12%) | called by muse, mutect2, varscan2
- SIGLEC12 | c.374G>T p.R125I | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- SLC15A1 | c.1417G>T p.V473L | Missense Mutation (SNP) | VAF 49/170 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC22A24 | c.962G>T p.R321I | Missense Mutation (SNP) | VAF 40/183 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SLC4A10 | c.2218T>C p.S740P (on ENST00000446997 / NM_001354461.2; = p.S710P on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 64/264 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC4A7 | c.3090+2T>A p.X1030_splice | Splice Site (SNP) | VAF 31/142 reads (22%) | called by muse, varscan2
- SLC9B2 | c.959T>C p.L320P | Missense Mutation (SNP) | VAF 53/273 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLITRK1 | c.731C>A p.P244H | Missense Mutation (SNP) | VAF 60/299 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- SMARCA1 | c.559C>G p.Q187E | Missense Mutation (SNP) | VAF 171/270 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SOAT1 | c.340G>T p.A114S | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SORCS3 | c.1232C>A p.A411D | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.67); called by muse, mutect2, varscan2
- SORT1 | c.1339G>C p.E447Q | Missense Mutation (SNP) | VAF 50/297 reads (17%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SPOCK3 | c.390G>C p.Q130H | Missense Mutation (SNP) | VAF 35/190 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.406); called by muse, mutect2, varscan2
- SPTBN4 | c.5323G>C p.E1775Q | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SRRM2 | c.2820G>T p.R940S | Missense Mutation (SNP) | VAF 76/207 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- TAB3 | c.1144A>G p.R382G | Missense Mutation (SNP) | VAF 47/125 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TAF1 | c.1298-2A>G p.X433_splice (on ENST00000373790 / NM_138923.4; = p.X454_splice on NM_004606.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 34/73 reads (47%) | called by muse, mutect2, varscan2
- TBC1D2 | c.305G>T p.C102F | Missense Mutation (SNP) | VAF 48/188 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- TBC1D32 | c.3299T>A p.L1100H | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TCEA1 | c.64-1G>C p.X22_splice | Splice Site (SNP) | VAF 59/206 reads (29%) | called by muse, mutect2, varscan2
- TECTA | c.2526C>A p.F842L | Missense Mutation (SNP) | VAF 77/414 reads (19%) | SIFT tolerated (0.53); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- TEX101 | c.67G>C p.G23R (on ENST00000598265 / NM_001130011.3; = p.G41R on NM_031451.4) | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TEX55 | c.1239G>T p.Q413H | Missense Mutation (SNP) | VAF 66/300 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- TFAP2D | c.329C>A p.P110H | Missense Mutation (SNP) | VAF 66/432 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- TGFBI | c.1324G>C p.D442H | Missense Mutation (SNP) | VAF 82/354 reads (23%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- TLCD3B | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- TM7SF3 | c.272C>A p.T91K | Missense Mutation (SNP) | VAF 85/237 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- TMEM117 | c.192del p.W64* | Frame Shift Del (DEL) | VAF 56/291 reads (19%) | called by mutect2, pindel, varscan2
- TMEM131 | c.3113G>T p.G1038V | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMEM131 | c.3112G>T p.G1038* | Nonsense Mutation (SNP) | VAF 38/159 reads (24%) | called by muse, mutect2, varscan2
- TMEM132C | c.808G>T p.G270C | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TMEM135 | c.50A>G p.H17R | Missense Mutation (SNP) | VAF 89/438 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.463); called by muse, mutect2, varscan2
- TMEM200A | c.586dup p.Q196Pfs*35 | Frame Shift Ins (INS) | VAF 38/146 reads (26%) | called by mutect2, pindel, varscan2
- TMEM200A | c.1452G>T p.R484S | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TMX1 | c.529G>T p.V177L | Missense Mutation (SNP) | VAF 53/220 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- TNC | c.6344C>A p.A2115D | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.41); called by muse, mutect2, varscan2
- TNFAIP1 | c.104del p.G35Afs*12 | Frame Shift Del (DEL) | VAF 23/205 reads (11%) | called by mutect2, pindel, varscan2
- TNNT1 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 143/550 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- TPR | c.5744C>G p.S1915C | Missense Mutation (SNP) | VAF 86/358 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.788); called by muse, mutect2, varscan2
- TRIM56 | c.83T>A p.L28Q | Missense Mutation (SNP) | VAF 112/308 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TRIP12 | c.4465T>C p.Y1489H | Missense Mutation (SNP) | VAF 31/127 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2
- TRPM2 | c.4499G>A p.G1500E | Missense Mutation (SNP) | VAF 26/84 reads (31%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- TTLL11 | c.1858A>G p.I620V | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.151); called by muse, mutect2, varscan2
- TTN | c.66883A>T p.I22295F (on ENST00000591111; = p.I14871F on NM_003319.4) | Missense Mutation (SNP) | VAF 62/195 reads (32%) | PolyPhen benign (0.021); called by muse, mutect2, varscan2
- TTN | c.11616G>C p.M3872I (on ENST00000591111; = p.M3826I on NM_003319.4) | Missense Mutation (SNP) | VAF 128/435 reads (29%) | called by muse, mutect2, varscan2
- TTYH3 | c.1057A>C p.T353P | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UBA1 | c.2654T>G p.L885R | Missense Mutation (SNP) | VAF 65/177 reads (37%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- UHRF1BP1 | c.1540G>T p.E514* | Nonsense Mutation (SNP) | VAF 61/271 reads (23%) | called by muse, mutect2, varscan2
- WDR93 | c.1849C>A p.L617I | Missense Mutation (SNP) | VAF 24/172 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2, varscan2
- WEE2 | c.316C>A p.P106T | Missense Mutation (SNP) | VAF 46/158 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.028); called by muse, varscan2
- WHRN | c.1162G>C p.A388P | Missense Mutation (SNP) | VAF 45/388 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- WSCD1 | c.235C>A p.P79T | Missense Mutation (SNP) | VAF 61/202 reads (30%) | SIFT tolerated (0.43); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- ZBTB10 | c.998G>T p.G333V | Missense Mutation (SNP) | VAF 19/107 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZC3H18 | c.1403G>T p.R468L | Missense Mutation (SNP) | VAF 81/345 reads (23%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ZFAT | c.3211dup p.I1071Nfs*2 | Frame Shift Ins (INS) | VAF 24/258 reads (9%) | called by mutect2, pindel
- ZNF148 | c.746A>T p.H249L | Missense Mutation (SNP) | VAF 28/198 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF292 | c.1676A>T p.H559L | Missense Mutation (SNP) | VAF 66/265 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF426 | c.179A>T p.D60V | Missense Mutation (SNP) | VAF 75/252 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- ZNF493 | c.763G>T p.G255C | Missense Mutation (SNP) | VAF 50/273 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, varscan2
- ZNF573 | c.1383G>T p.Q461H (on ENST00000536220 / NM_001172692.1; = p.Q403H on NM_152360.3) | Missense Mutation (SNP) | VAF 40/207 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.69); called by muse, mutect2, varscan2
- ZNF814 | c.1491T>A p.C497* | Nonsense Mutation (SNP) | VAF 47/166 reads (28%) | called by muse, mutect2, varscan2
- ZNF865 | c.2744A>T p.Q915L | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.61); called by muse, mutect2, varscan2
- ADAMTSL1 | c.1524C>T p.F508= | Silent (SNP) | VAF 44/192 reads (23%) | catalogued as rs1437211698; called by muse, mutect2, varscan2
- ADAMTSL3 | c.870C>A p.L290= | Silent (SNP) | VAF 38/256 reads (15%) | called by muse, mutect2, varscan2
- ANK2 | c.1779G>A p.G593= | Silent (SNP) | VAF 82/469 reads (17%) | catalogued as COSV52186674; called by muse, mutect2, varscan2
- ANO5 | c.171G>A p.R57= | Silent (SNP) | VAF 91/372 reads (24%) | catalogued as rs748661426; called by muse, varscan2
- ARHGEF40 | c.4317G>T p.P1439= | Silent (SNP) | VAF 26/231 reads (11%) | catalogued as rs745583801; called by muse, mutect2, varscan2
- C21orf91 | c.459C>G p.G153= | Silent (SNP) | VAF 28/285 reads (10%) | called by muse, mutect2
- CACNA1E | c.1932T>A p.P644= | Silent (SNP) | VAF 23/230 reads (10%) | catalogued as COSV62408211; called by muse, mutect2, varscan2
- CD1A | c.810T>A p.A270= | Silent (SNP) | VAF 27/130 reads (21%) | called by muse, mutect2, varscan2
- CEP41 | c.129C>T p.L43= | Silent (SNP) | VAF 142/350 reads (41%) | catalogued as COSV56220610; called by muse, mutect2, varscan2
- CEP97 | c.1860A>G p.V620= | Silent (SNP) | VAF 34/131 reads (26%) | catalogued as rs1295357241; called by muse, mutect2, varscan2
- CFAP47 | c.8754G>A p.L2918= | Silent (SNP) | VAF 93/188 reads (49%) | called by muse, mutect2, varscan2
- CLPS | c.36C>G p.L12= | Silent (SNP) | VAF 20/252 reads (8%) | called by muse, mutect2
- CNTNAP5 | c.2256C>A p.S752= | Silent (SNP) | VAF 96/207 reads (46%) | called by muse, mutect2, varscan2
- CPNE4 | c.276G>T p.R92= | Silent (SNP) | VAF 22/305 reads (7%) | called by muse, mutect2
- CPNE5 | c.438C>A p.G146= | Silent (SNP) | VAF 68/335 reads (20%) | catalogued as COSV55197087; called by muse, mutect2, varscan2
- CRYGN | c.351C>G p.P117= | Silent (SNP) | VAF 11/82 reads (13%) | called by muse, mutect2, varscan2
- CSMD2 | c.3069A>C p.S1023= | Silent (SNP) | VAF 39/260 reads (15%) | called by muse, mutect2, varscan2
- CSMD3 | c.2145C>A p.P715= (on ENST00000297405 / NM_001363185.1; = p.P611= on NM_052900.3) | Silent (SNP) | VAF 11/172 reads (6%) | called by muse, mutect2
- CUX2 | c.1914G>T p.P638= | Silent (SNP) | VAF 12/88 reads (14%) | called by muse, mutect2, varscan2
- CYP2F1 | c.1128C>A p.A376= | Silent (SNP) | VAF 30/119 reads (25%) | catalogued as rs577128494; called by muse, mutect2, varscan2
- DACT3 | c.903C>T p.P301= | Silent (SNP) | VAF 4/23 reads (17%) | called by muse, mutect2, varscan2
- DGAT2L6 | c.213T>A p.A71= | Silent (SNP) | VAF 38/97 reads (39%) | called by muse, mutect2, varscan2
- DNAH14 | c.3207A>T p.I1069= (on ENST00000445597; = p.I1453= on NM_001367479.1) | Silent (SNP) | VAF 75/333 reads (23%) | called by muse, mutect2, varscan2
- DNMBP | c.1668G>T p.L556= | Silent (SNP) | VAF 141/309 reads (46%) | called by muse, mutect2, varscan2
- E4F1 | c.552A>G p.L184= | Silent (SNP) | VAF 44/101 reads (44%) | catalogued as rs757917390; called by muse, mutect2, varscan2
- EEF1D | c.213C>T p.S71= | Silent (SNP) | VAF 25/152 reads (16%) | catalogued as rs757283733; called by muse, mutect2, varscan2
- EPHA6 | c.2296C>A p.R766= (on ENST00000389672 / NM_001080448.3; = p.R158= on NM_173655.4) | Silent (SNP) | VAF 56/263 reads (21%) | catalogued as rs139774071, COSV67592554; called by muse, mutect2, varscan2
- FGD5 | c.1503C>A p.T501= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as rs114002769; called by muse, mutect2, varscan2
- FLG | c.1197C>A p.A399= | Silent (SNP) | VAF 119/462 reads (26%) | called by muse, mutect2, varscan2
- FTSJ1 | c.621G>A p.P207= | Silent (SNP) | VAF 129/283 reads (46%) | catalogued as rs782597073, COSV50026226; called by muse, mutect2, varscan2
- GABBR1 | c.504C>T p.R168= | Silent (SNP) | VAF 70/284 reads (25%) | catalogued as rs1049475813; called by muse, mutect2, varscan2
- GAK | c.1137G>T p.R379= | Silent (SNP) | VAF 76/312 reads (24%) | called by muse, mutect2, varscan2
- GPC2 | c.267G>T p.V89= | Silent (SNP) | VAF 138/354 reads (39%) | called by muse, mutect2, varscan2
- GPRIN2 | c.912A>G p.P304= | Silent (SNP) | VAF 48/476 reads (10%) | catalogued as rs986530257; called by muse, mutect2, varscan2
- GRIN2B | c.2001C>T p.S667= | Silent (SNP) | VAF 78/370 reads (21%) | catalogued as rs200392452; ClinVar: likely benign; called by muse, mutect2, varscan2
- GSE1 | c.2937C>A p.A979= | Silent (SNP) | VAF 100/490 reads (20%) | called by muse, mutect2, varscan2
- HNRNPA3 | c.315G>T p.V105= | Silent (SNP) | VAF 59/143 reads (41%) | called by muse, mutect2, varscan2
- HSPB6 | c.336C>T p.F112= | Silent (SNP) | VAF 27/159 reads (17%) | called by muse, mutect2, varscan2
- HYDIN | c.5854C>A p.R1952= | Silent (SNP) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- IGHG3 | c.1299C>T p.T433= | Silent (SNP) | VAF 59/514 reads (11%) | catalogued as rs1465316430; called by muse, mutect2, varscan2
- IGHV3-33 | c.81G>A p.G27= | Silent (SNP) | VAF 66/233 reads (28%) | catalogued as rs1555493824; called by muse, mutect2, varscan2
- IGKV1-17 | c.270G>T p.G90= | Silent (SNP) | VAF 99/483 reads (20%) | catalogued as rs765692646; called by mutect2, varscan2
- KCNB1 | c.723C>A p.T241= | Silent (SNP) | VAF 31/121 reads (26%) | called by muse, mutect2, varscan2
- KCNIP4 | c.345C>T p.F115= | Silent (SNP) | VAF 33/239 reads (14%) | called by muse, mutect2, varscan2
- KCNMA1 | c.1368C>T p.F456= | Silent (SNP) | VAF 213/522 reads (41%) | called by muse, mutect2, varscan2
- KCP | c.12C>T p.V4= | Silent (SNP) | VAF 25/186 reads (13%) | called by muse, mutect2, varscan2
- KIAA1109 | c.11586A>C p.L3862= | Silent (SNP) | VAF 82/396 reads (21%) | called by muse, mutect2, varscan2
- KIF21B | c.3279C>A p.L1093= | Silent (SNP) | VAF 44/103 reads (43%) | called by muse, varscan2
- KLHL30 | c.729G>A p.Q243= | Silent (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- KLHL31 | c.1686G>T p.A562= | Silent (SNP) | VAF 181/520 reads (35%) | called by muse, mutect2, varscan2
- KPNA4 | c.330A>G p.L110= | Silent (SNP) | VAF 33/178 reads (19%) | called by muse, mutect2, varscan2
- KRBA1 | c.825T>C p.C275= | Silent (SNP) | VAF 50/428 reads (12%) | called by muse, mutect2, varscan2
- KRT28 | c.267C>A p.T89= | Silent (SNP) | VAF 110/342 reads (32%) | called by muse, varscan2
- LAMTOR3 | c.123A>G p.P41= | Silent (SNP) | VAF 55/297 reads (19%) | called by muse, mutect2, varscan2
- LIPI | c.144A>C p.L48= | Silent (SNP) | VAF 21/130 reads (16%) | called by muse, mutect2, varscan2
- MAGEB6 | c.723C>A p.S241= | Silent (SNP) | VAF 23/64 reads (36%) | called by muse, mutect2, varscan2
- MALSU1 | c.111G>A p.L37= | Silent (SNP) | VAF 34/213 reads (16%) | catalogued as rs1250977880; called by muse, mutect2, varscan2
- MAST1 | c.3642G>A p.T1214= | Silent (SNP) | VAF 46/190 reads (24%) | catalogued as rs375566974; called by muse, mutect2, varscan2
- MC3R | c.642G>A p.A214= | Silent (SNP) | VAF 47/333 reads (14%) | called by muse, mutect2, varscan2
- MGAM2 | c.4965G>A p.K1655= | Silent (SNP) | VAF 93/280 reads (33%) | catalogued as COSV72176331; called by muse, varscan2
- MS4A6E | c.351G>T p.L117= | Silent (SNP) | VAF 43/173 reads (25%) | called by muse, mutect2, varscan2
- MYH8 | c.3586C>A p.R1196= | Silent (SNP) | VAF 72/330 reads (22%) | catalogued as COSV67966297; called by muse, varscan2
- MYH8 | c.3585T>A p.L1195= | Silent (SNP) | VAF 73/328 reads (22%) | called by muse, varscan2
- MYT1 | c.909G>A p.E303= | Silent (SNP) | VAF 24/124 reads (19%) | catalogued as rs1169280249, COSV60505548; called by muse, varscan2
- NAV3 | c.387T>C p.N129= | Silent (SNP) | VAF 18/94 reads (19%) | called by muse, mutect2, varscan2
- NCOA3 | c.31C>T p.L11= | Silent (SNP) | VAF 20/123 reads (16%) | catalogued as COSV100508485; called by muse, mutect2, varscan2
- NEGR1 | c.708C>T p.T236= | Silent (SNP) | VAF 24/178 reads (13%) | called by muse, mutect2, varscan2
- NOA1 | c.1062C>G p.L354= | Silent (SNP) | VAF 54/231 reads (23%) | called by muse, mutect2, varscan2
- OLFM3 | c.678A>T p.T226= (on ENST00000338858 / NM_001288821.1; = p.T206= on NM_058170.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/211 reads (19%) | called by muse, mutect2, varscan2
- OR10G4 | c.594C>T p.I198= | Silent (SNP) | VAF 59/301 reads (20%) | catalogued as COSV57977490; called by muse, mutect2, varscan2
- OR10J3 | c.126C>G p.G42= | Silent (SNP) | VAF 125/415 reads (30%) | called by muse, mutect2
- OR2W3 | c.90C>A p.V30= | Silent (SNP) | VAF 25/217 reads (12%) | called by muse, mutect2, varscan2
- OR52J3 | c.330T>A p.T110= | Silent (SNP) | VAF 54/202 reads (27%) | called by muse, mutect2, varscan2
- P2RY8 | c.105G>T p.A35= | Silent (SNP) | VAF 73/383 reads (19%) | catalogued as COSV101184038, COSV67177030; called by muse, mutect2, varscan2
- PACS1 | c.39C>G p.G13= | Silent (SNP) | VAF 10/60 reads (17%) | called by muse, mutect2, varscan2
- PCM1 | c.2127T>C p.N709= | Silent (SNP) | VAF 25/151 reads (17%) | called by muse, mutect2, varscan2
- PI3 | c.324T>C p.S108= | Silent (SNP) | VAF 22/210 reads (10%) | catalogued as rs1029241821, COSV54782875; called by muse, mutect2
- PIEZO2 | c.6939C>T p.G2313= | Silent (SNP) | VAF 40/264 reads (15%) | called by mutect2, varscan2
- PML | c.1147C>T p.L383= | Silent (SNP) | VAF 42/208 reads (20%) | catalogued as COSV99167940; called by muse, mutect2, varscan2
- POGLUT2 | c.78G>A p.Q26= | Silent (SNP) | VAF 21/128 reads (16%) | catalogued as COSV99959192; called by muse, mutect2, varscan2
- POLQ | c.7602C>T p.F2534= | Silent (SNP) | VAF 28/320 reads (9%) | catalogued as rs1191548844; called by muse, mutect2
- PPP6R3 | c.663G>T p.L221= | Silent (SNP) | VAF 43/219 reads (20%) | called by muse, mutect2, varscan2
- PREX1 | c.609G>T p.P203= | Silent (SNP) | VAF 47/163 reads (29%) | catalogued as rs1453828211; called by muse, mutect2, varscan2
- PRR16 | c.912G>C p.V304= (on ENST00000407149 / NM_001300783.2; = p.V281= on NM_016644.2) | Silent (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- RIPK4 | c.354G>T p.R118= | Silent (SNP) | VAF 101/397 reads (25%) | called by muse, mutect2, varscan2
- SCN11A | c.166C>T p.L56= | Silent (SNP) | VAF 45/421 reads (11%) | called by muse, mutect2, varscan2
- SCN2A | c.1971C>A p.V657= | Silent (SNP) | VAF 24/122 reads (20%) | catalogued as rs149230197; called by muse, mutect2, varscan2
- SERPINA1 | c.264C>T p.L88= | Silent (SNP) | VAF 7/59 reads (12%) | called by muse, mutect2, varscan2
- SIGLEC1 | c.2952A>G p.P984= | Silent (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- SLC13A1 | c.396C>T p.A132= | Silent (SNP) | VAF 28/185 reads (15%) | called by muse, mutect2, varscan2
- SLC35G4 | c.252C>A p.A84= | Silent (SNP) | VAF 67/405 reads (17%) | called by mutect2, varscan2
- SLC49A4 | c.1224C>A p.V408= | Silent (SNP) | VAF 63/264 reads (24%) | catalogued as COSV53746296; called by muse, mutect2, varscan2
- SNAP91 | c.1128C>A p.A376= | Silent (SNP) | VAF 65/233 reads (28%) | called by muse, mutect2, varscan2
- SPP1 | c.183G>A p.V61= | Silent (SNP) | VAF 62/258 reads (24%) | called by muse, mutect2, varscan2
- TACC2 | c.2967G>T p.G989= | Silent (SNP) | VAF 184/424 reads (43%) | called by muse, mutect2, varscan2
- TFAP2D | c.330C>A p.P110= | Silent (SNP) | VAF 64/434 reads (15%) | catalogued as COSV99148172; called by muse, mutect2, varscan2
- TMEM119 | c.486C>A p.P162= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV67188807, COSV67188872; called by muse, mutect2, varscan2
- TMEM132B | c.1578C>A p.T526= | Silent (SNP) | VAF 49/248 reads (20%) | called by muse, varscan2
- TMPO | c.387G>T p.V129= | Silent (SNP) | VAF 84/358 reads (23%) | catalogued as COSV54125104; called by muse, mutect2, varscan2
- TNNI3K | c.2046C>A p.I682= | Silent (SNP) | VAF 42/252 reads (17%) | called by muse, mutect2, varscan2
- TRPM5 | c.309C>T p.I103= | Silent (SNP) | VAF 57/197 reads (29%) | called by muse, mutect2, varscan2
- TRUB1 | c.216C>T p.F72= | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as rs981976400, COSV100075930; called by muse, mutect2, varscan2
- TSPY2 | c.468T>A p.P156= | Silent (SNP) | VAF 41/931 reads (4%) | called by muse, mutect2
- UNC5D | c.807T>C p.G269= | Silent (SNP) | VAF 26/180 reads (14%) | catalogued as rs746374970; called by muse, mutect2, varscan2
- VSIG8 | c.90G>A p.E30= | Silent (SNP) | VAF 24/238 reads (10%) | catalogued as rs750955705; called by muse, mutect2
- WNK1 | c.5550A>T p.S1850= (on ENST00000315939 / NM_018979.4; = p.S1602= on NM_014823.3) | Silent (SNP) | VAF 171/779 reads (22%) | called by muse, mutect2, varscan2
- XIRP1 | c.1431G>A p.Q477= | Silent (SNP) | VAF 99/293 reads (34%) | called by muse, mutect2, varscan2
- ZFHX3 | c.2934G>C p.A978= | Silent (SNP) | VAF 43/308 reads (14%) | catalogued as COSV51707890; called by muse, mutect2, varscan2
- ZFPM2 | c.1263C>A p.P421= | Silent (SNP) | VAF 311/711 reads (44%) | catalogued as rs768549497, COSV101023685; called by muse, mutect2, varscan2
- ZNF311 | c.1095G>T p.G365= | Silent (SNP) | VAF 63/272 reads (23%) | called by muse, mutect2, varscan2
- AC004947.2 | n.106C>T | RNA (SNP) | VAF 34/210 reads (16%) | called by muse, mutect2, varscan2
- AC078880.2 | n.251A>G | RNA (SNP) | VAF 74/342 reads (22%) | called by muse, mutect2, varscan2
- AC107023.1 | n.26-6173G>T | Intron (SNP) | VAF 70/407 reads (17%) | called by muse, mutect2, varscan2
- AC107023.1 | n.25+486G>T | Intron (SNP) | VAF 34/160 reads (21%) | called by muse, mutect2, varscan2
- ADAMTS20 | c.-1C>A | 5'UTR (SNP) | VAF 36/159 reads (23%) | called by muse, mutect2, varscan2
- AHNAK | c.*67C>T | 3'UTR (SNP) | VAF 33/126 reads (26%) | catalogued as rs769805147; called by muse, mutect2, varscan2
- AHSA2P | n.95G>T | RNA (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- AL359195.2 | n.3305A>C | RNA (SNP) | VAF 127/343 reads (37%) | called by muse, mutect2, varscan2
- ARHGEF4 | c.-496G>T | 5'UTR (SNP) | VAF 48/235 reads (20%) | called by muse, mutect2, varscan2
- B4GALNT1 | chr12:57622933 A>T | 3'Flank (SNP) | VAF 48/201 reads (24%) | catalogued as rs776542661; called by muse, mutect2, varscan2
- C12orf77 | n.620C>T | RNA (SNP) | VAF 30/202 reads (15%) | called by muse, varscan2
- C19orf12 | chr19:29700712 C>A | 3'Flank (SNP) | VAF 71/396 reads (18%) | called by muse, mutect2, varscan2
- CD276 | c.-55+6237G>T | Intron (SNP) | VAF 45/184 reads (24%) | called by mutect2, varscan2
- COL25A1 | c.493-825C>A | Intron (SNP) | VAF 48/239 reads (20%) | called by muse, mutect2, varscan2
- COL4A2 | c.1340-388G>T | Intron (SNP) | VAF 134/834 reads (16%) | catalogued as rs1409260296; called by muse, varscan2
- CRABP1 | c.249+36C>T | Intron (SNP) | VAF 25/217 reads (12%) | catalogued as rs757084444; called by muse, mutect2, varscan2
- CRB1 | c.1172-7089G>T | Intron (SNP) | VAF 14/133 reads (11%) | called by muse, mutect2, varscan2
- DNMT3B | c.-83del | 5'UTR (DEL) | VAF 12/103 reads (12%) | called by mutect2, pindel, varscan2
- EIF3IP1 | n.212C>G | RNA (SNP) | VAF 38/287 reads (13%) | catalogued as rs757358533; called by muse, mutect2, varscan2
- FAM207A | chr21:44935780 G>T | 5'Flank (SNP) | VAF 30/110 reads (27%) | called by muse, mutect2, varscan2
- FAM27E5 | n.448A>C | RNA (SNP) | VAF 42/169 reads (25%) | called by muse, mutect2, varscan2
- FCRL2 | c.884-15C>A | Intron (SNP) | VAF 64/303 reads (21%) | called by muse, mutect2, varscan2
- FCRLB | c.574+272G>A | Intron (SNP) | VAF 109/271 reads (40%) | called by muse, mutect2, varscan2
- GFOD1 | c.253+16730G>A | Intron (SNP) | VAF 32/152 reads (21%) | called by muse, varscan2
- GLRXP3 | n.145A>C | RNA (SNP) | VAF 87/370 reads (24%) | called by muse, mutect2, varscan2
- H3-4 | c.-29G>A | 5'UTR (SNP) | VAF 69/258 reads (27%) | catalogued as rs556685275; called by muse, mutect2, varscan2
- HBE1 | c.-267+102455C>A | Intron (SNP) | VAF 57/200 reads (29%) | called by muse, mutect2, varscan2
- IGLV3-21 | c.-57C>G | 5'UTR (SNP) | VAF 79/321 reads (25%) | catalogued as rs960960856; called by muse, mutect2, varscan2
- IL9R | c.29-20C>A | Intron (SNP) | VAF 97/251 reads (39%) | called by muse, mutect2, varscan2
- KIAA1109 | c.10540-243G>T | Intron (SNP) | VAF 57/239 reads (24%) | called by muse, mutect2, varscan2
- LINC02872 | n.270G>T | RNA (SNP) | VAF 12/93 reads (13%) | called by muse, mutect2, varscan2
- LONRF3 | c.1812-127C>T | Intron (SNP) | VAF 19/90 reads (21%) | catalogued as rs1280405915; called by muse, mutect2, varscan2
- LRRC7 | c.647+35208dup | Intron (INS) | VAF 15/136 reads (11%) | called by mutect2, pindel
- METTL22 | c.*247C>T | 3'UTR (SNP) | VAF 104/339 reads (31%) | called by muse, mutect2, varscan2
- MIR9-1 | chr1:156420302 C>A | 3'Flank (SNP) | VAF 120/490 reads (24%) | catalogued as rs777377928; called by muse, mutect2, varscan2
- MUC19 | n.5736C>A | RNA (SNP) | VAF 48/221 reads (22%) | called by muse, mutect2, varscan2
- NDUFV1 | chr11:67604935 G>A | 5'Flank (SNP) | VAF 61/293 reads (21%) | called by muse, mutect2, varscan2
- NEB | c.-7T>C | 5'UTR (SNP) | VAF 40/187 reads (21%) | called by muse, mutect2, varscan2
- OFCC1 | n.2427G>C | RNA (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2, varscan2
- PDGFA | c.*6C>A | 3'UTR (SNP) | VAF 36/237 reads (15%) | called by muse, mutect2, varscan2
- PRKCSH | c.79+25G>A | Intron (SNP) | VAF 104/346 reads (30%) | called by muse, mutect2, varscan2
- RPLP0P2 | n.1096G>T | RNA (SNP) | VAF 97/384 reads (25%) | called by muse, mutect2, varscan2
- SLC26A6 | c.586-9G>T | Intron (SNP) | VAF 44/146 reads (30%) | catalogued as COSV50840331; called by muse, mutect2, varscan2
- SUPT20H | c.1211+81G>C | Intron (SNP) | VAF 24/61 reads (39%) | called by muse, mutect2, varscan2
- SV2C | c.581-21253C>T | Intron (SNP) | VAF 88/384 reads (23%) | called by muse, mutect2, varscan2
- TAF1 | c.4322-4621A>G | Intron (SNP) | VAF 37/78 reads (47%) | called by muse, mutect2, varscan2
- TCP10L3 | n.2533G>T | RNA (SNP) | VAF 38/166 reads (23%) | catalogued as COSV64751069, COSV64752128; called by muse, varscan2
- TLE4 | c.46-349G>T | Intron (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2, varscan2
- TRIP10 | c.-29G>T | 5'UTR (SNP) | VAF 23/68 reads (34%) | called by muse, varscan2
- VPS9D1 | c.176-48T>C | Intron (SNP) | VAF 23/94 reads (24%) | called by muse, mutect2, varscan2
- WDR75 | c.216+743C>A | Intron (SNP) | VAF 33/191 reads (17%) | catalogued as rs994535200; called by muse, mutect2, varscan2
- Y_RNA | chr7:23490831 G>A | 3'Flank (SNP) | VAF 85/427 reads (20%) | catalogued as rs1274298987; called by muse, mutect2, varscan2
- ZBTB37 | chr1:173867733 T>A | 5'Flank (SNP) | VAF 53/255 reads (21%) | called by muse, mutect2, varscan2
- ZEB2 | c.73+4931G>T | Intron (SNP) | VAF 89/545 reads (16%) | called by muse, mutect2, varscan2
- ZIK1 | c.-49del | 5'UTR (DEL) | VAF 23/80 reads (29%) | called by mutect2, pindel, varscan2
- ZNF451 | c.186+1512G>T | Intron (SNP) | VAF 45/121 reads (37%) | called by muse, mutect2, varscan2
- ZNF483 | c.722-2210A>C | Intron (SNP) | VAF 37/142 reads (26%) | catalogued as rs1433128522; called by muse, mutect2, varscan2
- ZNF496 | c.651+425A>T | Intron (SNP) | VAF 32/151 reads (21%) | called by muse, mutect2, varscan2
- ZNF530 | c.-30C>T | 5'UTR (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
